Somatic mutation profile of tumor specimen TCGA-77-8145-01A (aliquot TCGA-77-8145-01A-11D-2244-08) from TCGA case TCGA-77-8145, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.1 years (26,707 days).
Specimen TCGA-77-8145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61ce447d-d7a4-4bb1-a87f-4fe9cc585f02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-8145-10A (Blood Derived Normal), aliquot TCGA-77-8145-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bdd67b7-e3f5-4424-898d-70b1b7dc2d48

The open-access MAF lists 136 somatic variants for this specimen: 114 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 19, Nonsense Mutation 12, Frame Shift Del 3, Frame Shift Ins 2, RNA 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH1 | c.4663G>T p.E1555* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as rs746342893, CM159417, COSV53027330, COSV53080774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 47/65 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM9 | c.2392T>C p.S798P | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs983116055, COSV101165189; called by muse, mutect2, varscan2
- AKIRIN2 | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100005133; called by muse, mutect2, varscan2
- ANAPC1 | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV100594462; called by muse, mutect2, varscan2
- APC | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV57338695, COSV99964458; called by muse, mutect2, varscan2
- APOA4 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63360059; called by muse, mutect2, varscan2
- ARHGAP33 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV99137402; called by muse, mutect2, varscan2
- BRINP1 | c.1757G>C p.R586P | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV56317077, COSV99774056; called by muse, mutect2, varscan2
- C2CD3 | c.5614A>C p.T1872P | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV100486134, COSV58099920; called by muse, mutect2, varscan2
- CACNA1E | c.4735C>T p.R1579* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs1418737979, COSV100701179; called by muse, mutect2, varscan2
- CAMK2D | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV56427119, COSV99592985; called by muse, mutect2, varscan2
- CCT6A | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99303176; called by muse, mutect2, varscan2
- CMYA5 | c.1193G>A p.C398Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV101483726; called by muse, mutect2, varscan2
- CNTNAP4 | c.2825T>A p.L942Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100268954; called by muse, mutect2, varscan2
- COX5B | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.116); catalogued as COSV99300224; called by muse, varscan2
- COX5B | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99300225; called by muse, varscan2
- CPAMD8 | c.4126C>T p.P1376S (on ENST00000651564; = p.P1329S on NM_015692.5) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.209); catalogued as COSV101488348; called by muse, mutect2, varscan2
- CRISP1 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as COSV100236530; called by muse, mutect2, varscan2
- DAZL | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV99167453; called by muse, mutect2, varscan2
- DLC1 | c.2597G>C p.R866P (on ENST00000276297 / NM_001348081.2; = p.R429P on NM_006094.5) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV99360394; called by muse, mutect2
- DNAH5 | c.13054C>T p.R4352W | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530188302, COSV99443626; called by muse, mutect2, varscan2
- DRC7 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100395329, COSV61058265; called by muse, mutect2, varscan2
- E2F8 | c.2335C>T p.Q779* | Nonsense Mutation (SNP) | VAF 21/109 reads (19%) | catalogued as COSV100001232, COSV51464270; called by muse, mutect2, varscan2
- E4F1 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.177); catalogued as rs757261374, COSV100065277; called by muse, mutect2, varscan2
- ELFN2 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV101297448, COSV68744039; called by muse, mutect2, varscan2
- FAM135B | c.2527G>A p.G843R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as rs777524756, COSV52732717, COSV52744671; called by muse, mutect2, varscan2
- FGF14 | c.472T>C p.S158P | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101084080; called by muse, mutect2, varscan2
- FLVCR2 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs761933931, COSV99470961; called by muse, mutect2, varscan2
- FOXN3 | c.1247C>T p.S416F (on ENST00000261302; = p.S394F on NM_005197.4) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1290798583, COSV99725560; called by muse, mutect2, varscan2
- GALNT17 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100351772, COSV61165138; called by muse, mutect2, varscan2
- GCG | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 85/309 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV64962367; called by muse, mutect2, varscan2
- GLP2R | c.926-1G>A p.X309_splice | Splice Site (SNP) | VAF 24/198 reads (12%) | catalogued as COSV99301427; called by muse, mutect2, varscan2
- GNPTAB | c.3686C>T p.A1229V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100171536; called by muse, mutect2
- GP5 | c.540C>A p.N180K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99755970; called by muse, mutect2, varscan2
- GPLD1 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100014852; called by muse, mutect2, varscan2
- GPR141 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.703); catalogued as COSV100550195, COSV100550303, COSV57733031; called by muse, mutect2, varscan2
- GPR149 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101078031; called by mutect2, varscan2
- GPR179 | c.1357C>T p.R453W (on ENST00000621958; = p.R452W on NM_001004334.4) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397355177; called by muse, mutect2, varscan2
- GRK5 | c.629A>T p.K210I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100962775; called by muse, mutect2
- HADHA | c.2138G>T p.C713F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66107153; called by muse, mutect2, varscan2
- HLA-B | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV69520365; called by muse, mutect2, varscan2
- HNRNPDL | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV99786976; called by muse, mutect2, varscan2
- ICE1 | c.3721G>C p.D1241H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99663373; called by muse, mutect2, varscan2
- IGF2BP3 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.641); catalogued as rs890261339, COSV99324849; called by muse, mutect2
- IGKV1D-42 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1398656510; called by muse, mutect2, varscan2
- IGKV2D-29 | c.303C>G p.S101R | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV101534350; called by muse, mutect2, varscan2
- IGSF1 | c.2950G>C p.G984R | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100811761; called by muse, mutect2, varscan2
- IL17RB | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99860952; called by muse, mutect2
- JCAD | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV100947987; called by muse, mutect2, varscan2
- KALRN | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV99561622; called by muse, mutect2, varscan2
- KCNA4 | c.1255C>A p.L419M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100068405; called by muse, mutect2, varscan2
- KDM2B | c.3473G>T p.G1158V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100997070; called by muse, mutect2, varscan2
- KIF1B | c.4309C>T p.R1437* (on ENST00000377086 / NM_001365952.1; = p.R1391* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV99822230; called by muse, mutect2, varscan2
- KMT2C | c.11947C>G p.Q3983E | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV100064873, COSV51463502; called by muse, mutect2, varscan2
- LNX1 | c.1492C>T p.H498Y (on ENST00000263925 / NM_001126328.3; = p.H402Y on NM_032622.2) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV99819301; called by mutect2, varscan2
- LRP2 | c.12883T>C p.W4295R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99785956; called by muse, mutect2, varscan2
- LRRC7 | c.359C>G p.S120* (on ENST00000651989 / NM_001370785.2; = p.S87* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99223856; called by muse, mutect2, varscan2
- MAGEB16 | c.817T>C p.Y273H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV101303260; called by muse, mutect2, varscan2
- NBAS | c.5880A>T p.K1960N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99866550; called by muse, mutect2, varscan2
- NFATC1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs758037357, COSV53701290; called by muse, mutect2, varscan2
- NOX4 | c.1598T>C p.I533T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs759412630, COSV99629247; called by muse, mutect2
- NPAS1 | c.575C>G p.S192* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101463915; called by muse, mutect2, varscan2
- NUDT6 | c.895A>G p.K299E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV99144543; called by muse, mutect2, varscan2
- OR12D3 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.436); catalogued as COSV101011058, COSV65830394; called by muse, mutect2, varscan2
- OR2F2 | c.655A>C p.I219L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.209); catalogued as COSV101283789; called by muse, mutect2, varscan2
- OR4C12 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.082); catalogued as COSV100078171; called by muse, mutect2, varscan2
- PCDH10 | c.2166G>T p.L722F | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99992689; called by muse, mutect2, varscan2
- PPP1R7 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.12); catalogued as rs1423969541, COSV99297582; called by muse, mutect2
- PTF1A | c.957A>T p.E319D | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100919556; called by muse, mutect2, varscan2
- RBSN | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376613564; called by muse, mutect2, varscan2
- RELN | c.7102A>C p.T2368P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV100631964, COSV99067067; called by muse, mutect2, varscan2
- RNASE12 | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100250427; called by muse, mutect2, varscan2
- RYR1 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158533136, COSV100614113; called by muse, mutect2, varscan2
- SAGE1 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.121); catalogued as COSV61011911; called by muse, mutect2, varscan2
- SAP30BP | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV99502626; called by muse, mutect2, varscan2
- SCN1A | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100318863; called by muse, mutect2, varscan2
- SCN2A | c.5641G>C p.E1881Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV99329666; called by muse, mutect2, varscan2
- SELPLG | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as COSV99947158; called by muse, mutect2, varscan2
- SERPINB3 | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV99379516; called by muse, mutect2, varscan2
- SLC37A1 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs370225564; called by muse, mutect2, varscan2
- SOGA3 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.034); catalogued as COSV100846722; called by muse, mutect2
- SP7 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as rs1179825039, COSV100381900; called by muse, mutect2, varscan2
- SULF1 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs112367866, COSV99481765; called by muse, mutect2, varscan2
- TACR1 | c.1035G>T p.Q345H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV59485813; called by muse, mutect2, varscan2
- TFEC | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99623736; called by muse, mutect2, varscan2
- THOC5 | c.1111A>G p.N371D | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV100803388; called by muse, mutect2, varscan2
- THSD7B | c.2737T>C p.Y913H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs957881346, COSV99742477; called by muse, mutect2, varscan2
- TLE2 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99503949; called by muse, mutect2
- TLK2 | c.1241G>T p.G414V (on ENST00000326270 / NM_001284333.2; = p.G392V on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV100408578; called by muse, mutect2, varscan2
- TOPORS | c.315A>G p.I105M | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV62118100; called by muse, mutect2, varscan2
- TTC21B | c.944G>T p.R315I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99691737; called by muse, mutect2, varscan2
- UCK1 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 117/192 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV100944072; called by muse, mutect2, varscan2
- UNC13C | c.5944C>G p.L1982V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99510108; called by muse, mutect2, varscan2
- USH2A | c.7250G>T p.S2417I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100227776; called by muse, mutect2, varscan2
- USP19 | c.3427G>T p.E1143* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV101296067; called by muse, mutect2
- VWCE | c.2125C>G p.R709G | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV100075477; called by muse, mutect2, varscan2
- XPO6 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV100484608; called by muse, mutect2, varscan2
- XRN2 | c.1615G>A p.V539M | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV101017876; called by muse, mutect2
- ZC3H18 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.528); catalogued as rs749128519, COSV99963747; called by muse, mutect2, varscan2
- ZFAT | c.122A>C p.N41T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1238909735, COSV100914106; called by muse, mutect2
- ZNF121 | c.1079G>T p.R360I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1194140370, COSV57551046; called by muse, mutect2, varscan2
- ZNF219 | c.2122G>T p.G708W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV100069862; called by muse, mutect2, varscan2
- ZNF398 | c.519G>T p.K173N (on ENST00000475153 / NM_170686.3; = p.K2N on NM_020781.4) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100246782; called by muse, mutect2, varscan2
- ZNF423 | c.705C>A p.C235* (on ENST00000563137 / NM_001379286.1; = p.C227* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as rs1555516019, COSV99279270; called by muse, mutect2, varscan2
- ZNF440 | c.1684G>T p.V562L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100407301; called by muse, mutect2, varscan2
- CHRM5 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCHS1 | c.1210T>C p.S404P | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGKV3-7 | c.97T>G p.L33V | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRK | c.1523del p.S508* | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- PARD3 | c.3127dup p.I1043Nfs*29 | Frame Shift Ins (INS) | VAF 15/112 reads (13%) | called by mutect2, pindel, varscan2
- PEX12 | c.1020del p.I341Sfs*11 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | called by mutect2, pindel, varscan2
- SPTA1 | c.3547del p.H1183Mfs*57 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- TMEM225 | c.667dup p.W223Lfs*75 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- ART3 | c.1026C>T p.I342= (on ENST00000355810 / NM_001377173.1; = p.I331= on NM_001179.6) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100587450; called by muse, mutect2, varscan2
- CHST5 | c.243C>T p.L81= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100291662; called by muse, mutect2, varscan2
- DNAH5 | c.1410T>C p.F470= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99443628; called by muse, mutect2, varscan2
- GRM7 | c.483C>G p.V161= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV100735266; called by muse, mutect2, varscan2
- GUCY2C | c.9G>T p.T3= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99663114; called by muse, mutect2, varscan2
- HGF | c.801G>T p.P267= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99735178; called by muse, mutect2, varscan2
- LRRC4B | c.1617G>C p.T539= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs375311127; called by muse, varscan2
- MYO18B | c.7347G>A p.R2449= | Silent (SNP) | VAF 79/181 reads (44%) | catalogued as COSV100122300; called by muse, mutect2, varscan2
- NOP9 | c.750T>G p.P250= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99350403; called by muse, mutect2, varscan2
- PEX12 | c.1023C>T p.I341= | Silent (SNP) | VAF 23/102 reads (23%) | called by mutect2, varscan2
- PLEKHA4 | c.912G>A p.E304= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV99611931; called by muse, mutect2, varscan2
- PLPPR5 | c.33C>T p.S11= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV99586856; called by muse, mutect2
- PSMF1 | c.792G>A p.P264= | Silent (SNP) | VAF 19/289 reads (7%) | catalogued as rs748009139; called by muse, mutect2
- PTPRF | c.2262C>T p.G754= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100740432; called by muse, mutect2, varscan2
- RGL4 | c.999G>A p.T333= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs367580463; called by muse, mutect2, varscan2
- SGIP1 | c.2217G>T p.V739= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs938986229, COSV99390098; called by muse, mutect2, varscan2
- TMEM119 | c.666T>C p.H222= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs750559528, COSV101219352; called by muse, mutect2, varscan2
- TTN | c.6630T>C p.D2210= (on ENST00000591111; = p.D2164= on NM_003319.4) | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs1234622480, COSV100589835; called by muse, mutect2, varscan2
- ZFHX3 | c.1152C>T p.A384= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs144650397; called by muse, mutect2, varscan2
- FKBP9 | c.*2C>T | 3'UTR (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99638800; called by muse, mutect2
- LINC02870 | n.433T>C | RNA (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- TMEM99 | n.918del | RNA (DEL) | VAF 7/31 reads (23%) | called by mutect2, varscan2
